Somatic mutation profile of tumor specimen BA2361D (aliquot aq-BA2361D) from BEATAML1.0 case 2444, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.8 years (20,369 days).
Specimen BA2361D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 199ff7d6-beef-4f8c-876e-b27f9604c2f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2504D (Solid Tissue Normal), aliquot aq-BA2504D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95dccec2-e504-46a0-85c1-5dc252f0e752

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DTD2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs17097904; called by muse, mutect2, varscan2
- MYH8 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1169419511, COSV101238084; called by muse, mutect2, varscan2
- DNAH5 | c.4737G>A p.S1579= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as rs938971019; called by muse, varscan2
- LONRF3 | c.1446C>T p.C482= (on ENST00000371628 / NM_001031855.3; = p.C441= on NM_024778.5) | Silent (SNP) | VAF 55/138 reads (40%) | catalogued as rs771774621; called by muse, mutect2, varscan2
- PPP1R9B | c.258G>T p.A86= | Silent (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
- KCNU1 | c.2010-17047T>G | Intron (SNP) | VAF 87/313 reads (28%) | called by muse, mutect2, varscan2
